Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A80Q, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A80Q-01A (Primary Tumor).

Unique Patient Identifier:

Short descriptive translation of the pathology report as provided by the

Date:

Material received:

Material: left Adrenal gland

Right adrenal gland

Macroscopic findings:

1. A 14 x 8 x 4 cm specimen. On the cutted surface a tumor surrounded by a fatty-connective tissue capsule with a soft, partially cystic appearance with hemorrhage (202 g).
2. Left adrenal: A 2 x 2 x 1 cm specimen (2 g). On the cutted surface yellow, lobulated fatty tissue and normal adrenal tissue with zonal organisation can be found.

Microscopic findings:

Histologically, at HE- and PAS-staining tumor tissue consists of polygonal cells with a ranular cytoplasm and hyperchromatic nuclei. The stroma is vascularized, the connective tissue capsule surrounds the tumor and normal adrenal tissue is focally attached to it. The PAS-staining reveals similar findings. The center of the tumor is hyanilized with a focal edema. At a certain part the retroperitoneal fat is invaded by tumor cells. The lymphatic vessels are filled with tumor cells.

2.: Histologically at HE- and PAS-staining adrenal tissue can be found. The medulla is enhanced and fills one third of the total adrenal diameter.

Diagnosis:

Pheochromocytoma of the left adrenal gland with lymphatic invasion. Normal adrenal tissue in the specimen 2. . A hyperplasia of the adrenal medulla can not be diagnosed.

Translated by:

Remark: In a separate pathology report the diagnosis of a lymphnode metastasis was made. The lymphnode was removed during the intial surgery.

ICD-O-3
Pheochromocytoma, malignant 8700/3
Site: ② Adrenal gland NOS C74.9
JWD 10/17/13

Source: NCI Genomic Data Commons file 12c06c9b-e770-4fb2-a724-5364e30d6127 (TCGA-WB-A80Q.41132DBE-7A9E-4FC8-9A80-86C3F408918A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).